CCDI case PBBVIM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b42c1c95-676c-4cf6-aff7-d51bcd51cbe6

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 7.4 years (2,685 days).

Biospecimens (3 samples)
- Sample 0DI3J2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI3JJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI3M2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
